Gene-level copy-number profile of tumor specimen TCGA-FD-A6TG-01A from TCGA case TCGA-FD-A6TG, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 73.6 years (26,893 days).
Specimen TCGA-FD-A6TG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6439c04b-4a11-46e0-8f62-3ec445fd62e4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A6TG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9d5045f2-93a1-43a6-8d44-7dee3d7f7da8

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 14; copy number 2: 732; copy number 3: 11,287; copy number 4: 11,371; copy number 5: 13,954; copy number 6: 11,596; copy number 7: 4,375; copy number 8: 3,432; copy number 9: 1,110; copy number 10: 370; copy number 11: 661; copy number 12: 49; copy number 13: 118; copy number 14: 60; copy number 15: 402; copy number 16: 107; copy number 17: 16; copy number 18: 53; copy number 19: 14; copy number 23: 26; copy number 24: 2; copy number 25: 11; copy number 28: 20; copy number 29: 1; copy number 33: 7; copy number 43: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A6TG-01A-11D-A32A-01): tumor purity 0.39, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:15,021,553–15,022,958, 2 genes: RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 1,533 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,775,954–172,752,924, 298 genes, copy number 11–17 (broad region; genes not listed).
- chr1:181,668,749–181,669,028, 1 gene, copy number 11: Metazoa_SRP.
- chr1:190,478,551–191,228,467, 10 genes, copy number 11: LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680.
- chr1:242,082,986–242,524,697, 1 gene, copy number 11 (within-gene range 10–11): PLD5.
- chr1:242,345,558–242,671,576, 4 genes, copy number 11: AL360271.2, RPL10AP5, AL360271.1, AC099785.1.
- chr2:83,522,814–90,011,184, 214 genes, copy number 11–14 (broad region; genes not listed).
- chr2:100,642,444–103,019,900, 47 genes, copy number 11: AC092845.1, NANOGNBP1, LINC01868, AC092168.1, AC092168.3, NPAS2, AC092168.2, NPAS2-AS1, AC016738.1, RPL31, TBC1D8, BBIP1P1, TBC1D8-AS1, CNOT11, RNF149, SNORD89, MIR5696, CREG2, AC092570.1, RFX8, LINC01870, RPS6P3, PRCPP1, AC093894.1, AC093894.2, MAP4K4, LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9, TMEM182, LINC01796, LINC01935, AC108051.1.
- chr3:9,600,748–14,489,349, 121 genes, copy number 11–16 (broad region; genes not listed).
- chr3:15,970,003–18,445,588, 33 genes, copy number 11: AC090946.1, GALNT15, AC090953.2, DPH3, OXNAD1, AC090953.1, RFTN1, AC090948.1, AC090948.2, AC090948.3, AC090948.4, AC010727.1, LINC00690, AC010139.1, DAZL, AC091493.1, CDYLP1, PLCL2, MIR3714, PLCL2-AS1, AC090644.1, TBC1D5, AC090960.1, AC140076.1, RNU7-10P, AC104451.1, AC104451.2, AC104297.1, PDCL3P3, AC132807.1, AC132807.2, SATB1, AC144521.1.
- chr3:18,538,673–18,539,899, 1 gene, copy number 11: RAD23BP1.
- chr5:25,909,503–26,013,025, 3 genes, copy number 12: MSNP1, AC113370.1, RNU4-43P.
- chr6:7,541,617–10,222,161, 22 genes, copy number 11 (within-gene range 9–11): DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1, AL355499.2, AL359378.1, SLC35B3, HULC, AL161437.1, AL137220.1, OFCC1, AL136226.1, AL354868.1, RNU6ATAC21P.
- chr6:18,522,735–23,404,132, 48 genes, copy number 11 (within-gene range 6–11): MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1.
- chr7:7,949,853–10,779,944, 27 genes, copy number 14 (within-gene range 9–14): AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2, ICA1, AC006042.1, AC007009.1, AC007128.1, AC007128.2, NXPH1, AC009500.1, AC004852.2, AC004852.1, AC004852.3, GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1, AC010991.1, AC004936.1, AC004879.1, U3, MGC4859, HSPA8P8, AC009945.1, AC004415.1.
- chr7:14,070,535–23,177,914, 110 genes, copy number 12–28 (within-gene range 8–28) (broad region; genes not listed).
- chr8:122,414,332–124,728,473, 63 genes, copy number 15–24 (within-gene range 10–24) (broad region; genes not listed).
- chr8:127,289,817–129,683,770, 28 genes, copy number 13 (within-gene range 7–13): CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr12:45,444,766–46,004,685, 10 genes, copy number 13: AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1.
- chr12:64,146,388–69,823,204, 139 genes, copy number 15–43 (within-gene range 10–43) (broad region; genes not listed).
- chr12:71,664,301–72,186,618, 11 genes, copy number 25 (within-gene range 8–25): THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1.
- chr16:76,107,283–78,066,761, 33 genes, copy number 11: AC099511.1, AC010528.1, RPL18P13, AC010528.2, CNTNAP4, AC106741.1, RN7SKP233, SNORD33, AC108125.1, LINC02125, AC106729.1, MIR4719, AC106734.1, AC106733.1, MON1B, SYCE1L, AC009139.2, VN2R10P, AC009139.1, ADAMTS18, AC025284.1, LINC02131, AC092724.1, NUDT7, AC092134.1, AC092134.3, VAT1L, AC092134.2, PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2.
- chr16:78,123,243–78,124,332, 1 gene, copy number 11: AC079414.3.
- chr16:78,495,926–78,796,362, 5 genes, copy number 12: AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1.
- chr17:58,420,167–64,413,776, 205 genes, copy number 15 (within-gene range 5–15) (broad region; genes not listed).
- chr19:37,312,837–39,385,710, 98 genes, copy number 15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
